Somatic mutation profile of tumor specimen ALCH-B4W6-TTP1-A (aliquot ALCH-B4W6-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4W6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.2 years (28,188 days).
Specimen ALCH-B4W6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9778711b-5203-4195-a916-fd6469e2e1da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4W6-NB1-A (Blood Derived Normal), aliquot ALCH-B4W6-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d19680f-89f2-4e53-85cc-5064f9a6b5be

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 4, Nonsense Mutation 2, Intron 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 58/538 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ADSL | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs754349909; called by muse, mutect2
- GORASP1 | c.974C>A p.P325H | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56533918; called by muse, mutect2
- HSPA8 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.066); catalogued as COSV57086384, COSV99914288; called by muse, mutect2
- KCNH5 | c.2412G>T p.K804N | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV59770567; called by muse, mutect2, varscan2
- PLCB4 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 51/479 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53795682; called by muse, mutect2, varscan2
- SUMO2 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV58813637; called by muse, mutect2
- TTN | c.81998T>C p.I27333T (on ENST00000591111; = p.I19909T on NM_003319.4) | Missense Mutation (SNP) | VAF 42/674 reads (6%) | PolyPhen possibly damaging (0.486); catalogued as rs762434090; ClinVar: likely benign; called by muse, mutect2
- AC099489.1 | c.3329C>T p.T1110I | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2
- BARX1 | c.489G>C p.K163N | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2
- BRPF3 | c.3119C>T p.P1040L | Missense Mutation (SNP) | VAF 63/416 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C6 | c.1257G>T p.R419S | Missense Mutation (SNP) | VAF 28/621 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.047); called by muse, mutect2
- CDC6 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 32/552 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- FBXL2 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 26/296 reads (9%) | called by muse, mutect2
- IL21R | c.74G>C p.C25S | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITGA10 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 15/263 reads (6%) | called by muse, mutect2
- LRRC43 | c.625G>C p.G209R | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- MED13 | c.5420G>T p.C1807F | Missense Mutation (SNP) | VAF 55/375 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MS4A3 | c.602G>T p.C201F | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2
- OR2D2 | c.350T>A p.V117E | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PDE4B | c.1102A>T p.M368L | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RBM10 | c.1950G>C p.Q650H | Missense Mutation (SNP) | VAF 29/346 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- SMPD4 | c.2122dup p.T708Nfs*16 (on ENST00000409031 / NM_017951.4; = p.T679Nfs*16 on NM_017751.4) | Frame Shift Ins (INS) | VAF 17/114 reads (15%) | called by mutect2, pindel, varscan2
- XIRP2 | c.8020G>A p.A2674T (on ENST00000628543; = p.A2849T on NM_152381.6) | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2
- ZC3H10 | c.196G>T p.V66L | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2
- DNAJC7 | c.1461G>A p.G487= | Silent (SNP) | VAF 21/190 reads (11%) | called by muse, mutect2, varscan2
- DSC2 | c.1326A>G p.P442= | Silent (SNP) | VAF 10/233 reads (4%) | called by muse, mutect2
- NF1 | c.2550G>A p.V850= | Silent (SNP) | VAF 36/319 reads (11%) | catalogued as rs772148227; ClinVar: likely benign; called by muse, mutect2, varscan2
- SETBP1 | c.633G>A p.Q211= | Silent (SNP) | VAF 24/462 reads (5%) | called by muse, mutect2
- CDC6 | c.1453-19C>T | Intron (SNP) | VAF 13/348 reads (4%) | called by muse, mutect2
- CLCN1 | c.774+451G>C | Intron (SNP) | VAF 8/183 reads (4%) | called by muse, mutect2
- JKAMP | c.-14G>A | 5'UTR (SNP) | VAF 15/360 reads (4%) | called by muse, mutect2
